Somatic mutation profile of tumor specimen 0DR3MC from CCDI case PBCFVD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.4 years (2,708 days).
Specimen 0DR3MC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc5cfb72-2d65-494d-a901-4c7bbde04d04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR3L3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3218f076-a7eb-410f-a2d5-b4fad2e3179e

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 3, Silent 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 171/398 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- DDX3X | c.974G>A p.R325H (on ENST00000399959; = p.R326H on NM_001356.5) | Missense Mutation (SNP) | VAF 205/238 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs797045025, CM158024, COSV101302329; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.15641G>A p.R5214H | Missense Mutation (SNP) | VAF 153/319 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123729, CM105480, COSV56427001, COSV99977974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 169/395 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60788908, COSV60805381; called by muse, mutect2, varscan2
- NAPSA | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1198090350; called by muse, mutect2, varscan2
- PCDHA11 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 23/651 reads (4%) | catalogued as COSV56502825; called by muse, mutect2
- SPANXN2 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0.1); catalogued as rs782507654, COSV65127843, COSV65127901; called by muse, mutect2
- TESPA1 | c.814C>T p.R272* (on ENST00000316577 / NM_001098815.3; = p.R134* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 227/538 reads (42%) | catalogued as rs759038034; called by muse, mutect2, varscan2
- ZNF98 | c.306T>A p.N102K | Missense Mutation (SNP) | VAF 128/422 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1568289712, COSV63335140, COSV63335366; called by muse, mutect2, varscan2
- BNIP3 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 170/344 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC141 | c.785C>G p.T262S | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- CCNC | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 143/160 reads (89%) | called by muse, mutect2, varscan2
- SLFN12L | c.1703del p.F568Sfs*2 (on ENST00000260908 / NM_001363830.1; = p.F586Sfs*2 on NM_001195790.1) | Frame Shift Del (DEL) | VAF 220/566 reads (39%) | called by mutect2, pindel, varscan2
- RALBP1 | c.24C>G p.P8= | Silent (SNP) | VAF 102/262 reads (39%) | catalogued as COSV50035635; called by muse, mutect2, varscan2
- TRMT13 | c.12C>T p.S4= | Silent (SNP) | VAF 181/458 reads (40%) | catalogued as rs768063485; called by muse, mutect2, varscan2
- DNAI4 | c.2014-46_2014-43del | Intron (DEL) | VAF 24/91 reads (26%) | catalogued as rs1237885716; called by mutect2, pindel, varscan2
